Somatic mutation profile of tumor specimen TCGA-DH-5142-01A (aliquot TCGA-DH-5142-01A-01D-1468-08) from TCGA case TCGA-DH-5142, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 29.2 years (10,678 days).
Specimen TCGA-DH-5142-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa14f7bb-f8b1-40dc-9e58-db7bebc3e36c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-5142-10A (Blood Derived Normal), aliquot TCGA-DH-5142-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3767524b-5662-4c94-84a7-1ed5dc4ba262

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 79/92 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs776318061, COSV67135614; called by muse, mutect2
- AMY2B | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 154/993 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs755109874, COSV100796249, COSV63715171; called by muse, mutect2, varscan2
- ATRX | c.4808A>G p.Q1603R | Missense Mutation (SNP) | VAF 86/113 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64880413; called by muse, mutect2, varscan2
- CACNA1B | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs775096777, COSV53116473, COSV99499754; called by muse, mutect2, varscan2
- CCDC158 | c.3176T>C p.I1059T | Missense Mutation (SNP) | VAF 36/427 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1172962953, COSV66356747; called by muse, mutect2
- CCNG2 | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 95/248 reads (38%) | catalogued as COSV60354318; called by muse, mutect2, varscan2
- COL27A1 | c.1681A>G p.K561E | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV61928904; called by muse, mutect2
- DNAH11 | c.4837G>T p.A1613S | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV60968072; called by muse, mutect2, varscan2
- GAS2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1372094047, COSV53410207; called by muse, mutect2
- GAS2L2 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs782603064; called by muse, mutect2
- LRP1B | c.5555C>A p.T1852K | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67251202; called by muse, mutect2
- MYH8 | c.2308G>C p.A770P | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67969319; called by muse, mutect2, varscan2
- MYO3A | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56340268; called by muse, mutect2
- OAF | c.466C>G p.P156A | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV61109617; called by muse, mutect2, varscan2
- OR1S1 | c.373A>T p.N125Y | Missense Mutation (SNP) | VAF 182/441 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58707915; called by muse, mutect2, varscan2
- PSD | c.1325T>G p.F442C | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV50051433; called by muse, mutect2
- PTPN18 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs11892325; called by muse, mutect2, varscan2
- RMI1 | c.1039C>G p.R347G | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs781655436, COSV57937142; called by muse, mutect2, varscan2
- RNASEL | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.185); catalogued as rs1474952281, COSV62377471; called by muse, mutect2
- RSPH14 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53270621; called by muse, mutect2, varscan2
- SIRPD | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV67546996; called by muse, mutect2, varscan2
- SMCO4 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54359751; called by muse, mutect2
- SNX17 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs772349518, COSV52006259; called by muse, varscan2
- SPTAN1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as COSV63988613; called by muse, mutect2, varscan2
- CACNA2D1 | c.1764C>T p.F588= (on ENST00000356253 / NM_001366867.1; = p.F569= on NM_000722.4) | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV62386171; called by muse, mutect2
- CATIP | c.1038C>T p.F346= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV56823670; called by muse, mutect2
- NEB | c.19887G>A p.V6629= | Silent (SNP) | VAF 75/223 reads (34%) | catalogued as COSV51438995; called by muse, mutect2, varscan2
- RHAG | c.36G>T p.L12= | Silent (SNP) | VAF 62/208 reads (30%) | catalogued as COSV57705391; called by muse, mutect2, varscan2
- TRPM6 | c.1074T>C p.S358= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as COSV62517204; called by muse, mutect2, varscan2
- UNC45B | c.726C>T p.C242= | Silent (SNP) | VAF 25/240 reads (10%) | catalogued as COSV52098534; called by muse, mutect2, varscan2
- ZNF713 | c.540A>C p.S180= (on ENST00000633730 / NM_001366796.2; = p.S193= on NM_182633.3) | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as COSV70057098; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15211A>C | Intron (SNP) | VAF 24/150 reads (16%) | catalogued as COSV101043112; called by muse, varscan2
